Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7218, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7218-01B (Primary Tumor).

Collection Date: [REDACTED]

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN ONE (0/1) LYMPH NODE EXAMINED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN TWO (0/2) LYMPH NODES EXAMINED.

PART 3:

PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL RETROBUBIC PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3+4=7, WITH A SMALL TERTIARY GLEASON PATTERN 5 COMPONENT (SLIDES 3JJ, 3NN). GLEASON PATTERN 4 AND 5 COMPONENTS COMPRISE APPROXIMATELY 20% OF THE SAMPLED PROSTATE TUMOR VOLUME.
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2 cm.
- C. CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE BENIGN.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- G. NO PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. TNM PATHOLOGIC STAGE: pT2c, N0, Mx.
- K. HISTOLOGIC GRADE = G3-4.
- L. NON-NEOPLASTIC PROSTATE WITH NODULAR HYPERPLASIA (SEE SYNOPSIS).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 7.4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	63.43gm
TUMOR SIZE:	Maximum dimension: 2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	No
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	3
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file f9c9ae5a-0cc4-4eb6-ae1b-669b0aedfefd (TCGA-EJ-7218.D1D8A1D3-24B1-4787-8925-A5A8FC19DF74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).